TCGA case TCGA-BP-4988 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9c8169e7-9193-41f5-878e-ed1af3b95422

Demographics
Sex at birth: male; Race: white; Age at index: 72 years; Vital status: Dead; Days to death: 828 days (2.3 years).

Diagnoses (3)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 72.8 years (26,576 days); Year of diagnosis: 2007; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1.
2. Prior malignancy of the lung (histology not recorded by GDC). Laterality: Left.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Laterality: Left; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fludarabine; Days to treatment start: -1,710 days (-4.7 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 828 days (2.3 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Calcium: Low.
- Leukocytes: Elevated.
- Platelets: Low.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-4988-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1.1; Shortest dimension: 0.3.
  Slide TCGA-BP-4988-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-BP-4988-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-BP-4988-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-4988-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1.3; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lung; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 1, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -1345.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy L lung adenocarcinoma treated with fludarabine and L lung bronchoalveolar cancer. No systemic chemotherapy or radiation.
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 828 days; disease-specific survival: no event (censored), 828 days; progression-free interval: no event (censored), 828 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-BP-4988-01): tumor purity 0.23, ploidy 2.05, whole-genome doublings 0 (call status: legacy_maf_call).
